Somatic mutation profile of tumor specimen TCGA-CU-A0YR-01A (aliquot TCGA-CU-A0YR-01A-12D-A10S-08) from TCGA case TCGA-CU-A0YR, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 84.0 years (30,674 days).
Specimen TCGA-CU-A0YR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83ea1c9e-e71d-4366-aef1-4f4d1e79c21d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CU-A0YR-10A (Blood Derived Normal), aliquot TCGA-CU-A0YR-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b24156d-3c68-42b2-a596-d759e10b173d

The open-access MAF lists 168 somatic variants for this specimen: 123 protein-altering or splice-affecting, 39 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 39, Nonsense Mutation 7, Frame Shift Del 4, Splice Site 4, Frame Shift Ins 3, 3'UTR 3, Intron 2, In Frame Del 2, 5'Flank 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.8662A>T p.I2888L | Missense Mutation (SNP) | VAF 59/153 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53726051; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 22/136 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.2074G>C p.D692H | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV53962541; called by muse, mutect2, varscan2
- ACD | c.1075C>A p.P359T (on ENST00000620338; = p.P270T on NM_022914.3) | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV54665895; called by muse, mutect2, varscan2
- ACE2 | c.974A>C p.Q325P | Missense Mutation (SNP) | VAF 121/206 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53023618; called by muse, mutect2, varscan2
- ADAM23 | c.1613C>A p.A538D | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52207801; called by muse, mutect2, varscan2
- ANKLE2 | c.787A>G p.T263A | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV61707781; called by muse, mutect2, varscan2
- ARID1B | c.4177C>G p.Q1393E | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as COSV51648744; called by muse, mutect2, varscan2
- ARMC3 | c.1543A>G p.N515D | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV53057129; called by muse, mutect2, varscan2
- ATP6V1H | c.148A>T p.I50F | Missense Mutation (SNP) | VAF 95/185 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as COSV62216827; called by muse, mutect2, varscan2
- ATRNL1 | c.3968T>G p.F1323C | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV58074088; called by muse, mutect2, varscan2
- BAP1 | c.673G>C p.D225H | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56230033, COSV56230601; called by muse, mutect2, varscan2
- BCL10 | c.56A>T p.D19V | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV65353485; called by muse, mutect2, varscan2
- BMX | c.2008C>T p.R670W | Missense Mutation (SNP) | VAF 63/200 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as rs1029888196, COSV53023604; called by muse, mutect2, varscan2
- BTNL2 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.185); catalogued as rs1171818199, COSV66630159; called by muse, mutect2, varscan2
- CBL | c.2599C>T p.Q867* | Nonsense Mutation (SNP) | VAF 281/492 reads (57%) | catalogued as COSV50654835; called by muse, mutect2, varscan2
- CD27 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as COSV56949521; called by muse, mutect2, varscan2
- CENPT | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.217); catalogued as COSV54648089; called by muse, mutect2
- CEP126 | c.1920A>T p.E640D | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.132); catalogued as COSV54821619; called by muse, mutect2, varscan2
- CMTR2 | c.797T>G p.L266R | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57602491; called by muse, mutect2, varscan2
- COL22A1 | c.4030C>T p.P1344S | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV57323070; called by muse, mutect2, varscan2
- COL6A6 | c.3147C>A p.H1049Q | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62017629; called by muse, mutect2, varscan2
- COMP | c.1475A>T p.Q492L | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1252223404, CM051434, COSV55873801; called by muse, mutect2, varscan2
- CPNE1 | c.1585A>G p.K529E (on ENST00000352393; = p.K534E on NM_003915.5) | Missense Mutation (SNP) | VAF 109/354 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.036); catalogued as COSV58289825; called by muse, mutect2, varscan2
- CPT1B | c.2236A>T p.N746Y | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV56415026; called by muse, mutect2
- CSF1R | c.181T>C p.Y61H | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs1423864756, COSV53828419; called by muse, mutect2, varscan2
- CTBP2 | c.49A>T p.I17F | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.033); catalogued as COSV61468750; called by muse, mutect2, varscan2
- CUBN | c.9244G>C p.D3082H | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV64707806, COSV64714555; called by muse, mutect2, varscan2
- DENND4C | c.925A>G p.T309A | Missense Mutation (SNP) | VAF 88/266 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV66821451; called by muse, mutect2, varscan2
- DLG5 | c.4766A>C p.K1589T | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV64946716; called by muse, mutect2, varscan2
- DNAJC13 | c.6430A>G p.I2144V | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV53445601; called by muse, varscan2
- DNM3 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 103/188 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as COSV62453024; called by muse, mutect2, varscan2
- DYSF | c.2790G>T p.W930C | Missense Mutation (SNP) | VAF 264/818 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs727503910, CM066563, COSV50267911; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELAPOR2 | c.1090-2A>G p.X364_splice (on ENST00000450689 / NM_001142749.3; = p.X197_splice on NM_152748.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 28/68 reads (41%) | catalogued as COSV51883994; called by mutect2, varscan2
- ELF3 | c.764_768del p.K255Ifs*44 | Frame Shift Del (DEL) | VAF 71/140 reads (51%) | catalogued as COSV62837177; called by mutect2, pindel, varscan2
- EP300 | c.49A>G p.K17E | Missense Mutation (SNP) | VAF 93/248 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54326083; called by muse, mutect2, varscan2
- ERCC2 | c.1820G>C p.G607A | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67266580; called by muse, mutect2, varscan2
- EVI2B | c.648G>C p.L216F | Missense Mutation (SNP) | VAF 61/243 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as COSV58363339; called by muse, mutect2, varscan2
- FAM169A | c.1900G>T p.D634Y | Missense Mutation (SNP) | VAF 59/281 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57187486; called by muse, mutect2, varscan2
- FGGY | c.28A>T p.R10W | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV58026238; called by muse, mutect2, varscan2
- FSIP1 | c.1264A>G p.I422V | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1187237758, COSV63223368; called by muse, mutect2, varscan2
- GLI3 | c.3691C>A p.L1231I | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV67885240, COSV67890559; called by muse, mutect2, varscan2
- GP1BA | c.316C>A p.Q106K | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56698608; called by muse, mutect2, varscan2
- GPX6 | c.249T>G p.N83K | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62656825; called by muse, mutect2, varscan2
- GTSE1 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71888921; called by muse, mutect2, varscan2
- HNRNPDL | c.1123G>A p.G375S | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.183); catalogued as COSV55022141; called by muse, mutect2, varscan2
- HNRNPL | c.1364A>G p.K455R | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.845); catalogued as COSV55491112; called by muse, mutect2, varscan2
- HOXB4 | c.669G>T p.L223F | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV60177996; called by muse, mutect2, varscan2
- IGF1R | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as rs776250673, COSV51270033; called by mutect2, varscan2
- INPP5A | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61246539; called by muse, mutect2, varscan2
- KAT6A | c.3244A>G p.R1082G | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.039); catalogued as COSV55902610, COSV55902630; called by muse, mutect2, varscan2
- KCNV2 | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs200353727; ClinVar: uncertain significance; called by muse, mutect2
- KEAP1 | c.1709-2A>G p.X570_splice | Splice Site (SNP) | VAF 37/84 reads (44%) | catalogued as COSV50261531; called by muse, mutect2, varscan2
- KPNB1 | c.1586A>G p.Y529C | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51594821; called by muse, mutect2, varscan2
- LAMA2 | c.1428del p.S476Rfs*65 | Frame Shift Del (DEL) | VAF 29/121 reads (24%) | catalogued as COSV70338520; called by pindel, varscan2
- LAMA3 | c.4244G>A p.G1415E | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as rs780195838, COSV58062285, COSV58072601; called by muse, varscan2
- LRIG3 | c.2177C>G p.P726R | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1048276059, COSV57860820, COSV57869770; called by muse, mutect2, varscan2
- LUC7L2 | c.623A>T p.D208V | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54923460; called by muse, mutect2, varscan2
- MIPOL1 | c.901C>G p.L301V | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as COSV59379320, COSV59383717; called by muse, mutect2, varscan2
- MIPOL1 | c.902T>A p.L301Q | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV59379334; called by muse, mutect2, varscan2
- MOV10 | c.22C>G p.R8G | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV54144214; called by muse, mutect2, varscan2
- MTREX | c.1514A>T p.D505V | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57923895; called by muse, mutect2, varscan2
- MYBPC3 | c.2449C>G p.R817G | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM160559, COSV57022934; called by muse, mutect2, varscan2
- MYOZ2 | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61084066; called by muse, varscan2
- NAA25 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV55701949; called by muse, mutect2, varscan2
- NBEA | c.5932A>G p.I1978V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.107); catalogued as COSV59760228; called by muse, mutect2, varscan2
- NES | c.4469A>G p.Q1490R | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV63960356; called by muse, mutect2, varscan2
- NKRF | c.2069A>G p.N690S | Missense Mutation (SNP) | VAF 52/78 reads (67%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.039); catalogued as COSV58660685; called by muse, mutect2, varscan2
- NLRP14 | c.2597C>T p.A866V | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as rs755827043, COSV55063984; called by muse, mutect2, varscan2
- NME4 | c.226-1G>A p.X76_splice | Splice Site (SNP) | VAF 147/490 reads (30%) | catalogued as rs1188290992, COSV54790977; called by muse, mutect2, varscan2
- NSD1 | c.605G>A p.G202D | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV61770682; called by muse, varscan2
- OGDH | c.2039G>A p.R680Q | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1380156561, COSV56045426; called by muse, mutect2, varscan2
- OR2V2 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 73/186 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV60314704; called by muse, mutect2, varscan2
- PAH | c.538A>T p.M180L | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV61013924; called by muse, mutect2, varscan2
- PCDHAC1 | c.2011T>C p.W671R | Missense Mutation (SNP) | VAF 64/331 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV53836719; called by muse, mutect2, varscan2
- PER1 | c.3103G>A p.A1035T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.767); catalogued as rs866940939, COSV57917295; called by muse, mutect2, varscan2
- PLEKHG2 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 92/303 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as rs762765271, COSV52678300; called by muse, mutect2, varscan2
- PLEKHM1 | c.1088C>G p.A363G | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.081); catalogued as COSV69598505; called by muse, mutect2, varscan2
- PNPLA7 | c.17A>G p.D6G | Missense Mutation (SNP) | VAF 34/256 reads (13%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV52994152; called by muse, mutect2, varscan2
- POLR3A | c.1709C>T p.S570L | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.186); catalogued as COSV64930226; called by muse, mutect2, varscan2
- POTED | c.1571G>C p.R524P | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV55046589; called by muse, varscan2
- PRAMEF12 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 58/424 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs377506368; called by muse, varscan2
- RAET1G | c.260G>T p.W87L | Missense Mutation (SNP) | VAF 138/362 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66273940, COSV66274958; called by muse, mutect2, varscan2
- RERE | c.748T>G p.F250V | Missense Mutation (SNP) | VAF 69/142 reads (49%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.992); catalogued as COSV61937136; called by muse, mutect2, varscan2
- SAMD11 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as rs771859258, COSV59703347; called by muse, mutect2, varscan2
- SCEL | c.1148A>G p.N383S (on ENST00000349847 / NM_144777.3; = p.N363S on NM_003843.4) | Missense Mutation (SNP) | VAF 95/306 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.073); catalogued as COSV62992873; called by muse, mutect2, varscan2
- SIM1 | c.1145C>G p.S382C | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.814); catalogued as rs774273867, COSV53489015, COSV99492653; called by muse, mutect2, varscan2
- SKIL | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 39/252 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs750266431, COSV52058248; called by muse, mutect2, varscan2
- SLC4A8 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs765091987, COSV60647639; called by muse, mutect2, varscan2
- SLC5A7 | c.155T>C p.L52S | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.309); catalogued as COSV50888899; called by muse, mutect2, varscan2
- SLC5A8 | c.465T>A p.N155K | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV65986977; called by muse, mutect2, varscan2
- TNFRSF9 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143524950; called by muse, mutect2, varscan2
- TOP3A | c.1105A>G p.I369V | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.491); catalogued as COSV58174868; called by muse, mutect2, varscan2
- TRPC4 | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 110/393 reads (28%) | catalogued as COSV58994311; called by muse, mutect2, varscan2
- TRPS1 | c.4G>A p.V2I (on ENST00000220888 / NM_001330599.2; = p.V15I on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV55226557; called by muse, mutect2, varscan2
- UGT2A3 | c.52G>A p.V18I | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs771394781, COSV52358778; called by muse, mutect2, varscan2
- UGT2B7 | c.124A>G p.I42V | Missense Mutation (SNP) | VAF 65/218 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as rs569411321, COSV59441920; called by muse, mutect2, varscan2
- VRK3 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763170632, COSV57464418; called by muse, mutect2, varscan2
- WWC2 | c.228C>G p.I76M | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.992); catalogued as COSV66712332; called by muse, mutect2, varscan2
- XIRP2 | c.6310G>A p.E2104K (on ENST00000628543; = p.E2279K on NM_152381.6) | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.123); catalogued as COSV54682650; called by muse, mutect2, varscan2
- XPOT | c.919A>G p.S307G | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV60343858; called by muse, mutect2, varscan2
- ZBTB32 | c.374A>C p.K125T | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV52889373; called by muse, mutect2, varscan2
- ZDHHC11 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 59/397 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.125); catalogued as rs768718254, COSV52062495; called by muse, mutect2, varscan2
- ZNF133 | c.361G>T p.D121Y (on ENST00000316358 / NM_001352454.2; = p.D120Y on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 91/307 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.332); catalogued as COSV60366153; called by muse, mutect2, varscan2
- ZNF317 | c.925G>T p.D309Y | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs1365757958, COSV56108307; called by muse, mutect2, varscan2
- ZNF317 | c.926A>T p.D309V | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.73); catalogued as COSV56108316; called by muse, mutect2, varscan2
- ZZEF1 | c.7885G>A p.E2629K | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as rs759914887, COSV67555927; called by muse, mutect2, varscan2
- ABCA13 | c.1278G>A p.W426* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- BMP8B | c.967C>T p.Q323* | Nonsense Mutation (SNP) | VAF 44/209 reads (21%) | called by muse, mutect2, varscan2
- CDADC1 | c.430+3_430+6dup | Frame Shift Ins (INS) | VAF 19/156 reads (12%) | called by mutect2, pindel, varscan2
- CDK11B | c.1516G>T p.G506C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNOT2 | c.34A>T p.K12* | Nonsense Mutation (SNP) | VAF 41/160 reads (26%) | called by muse, mutect2, varscan2
- CNOT2 | c.1621T>C p.*541Qext*65 | Nonstop Mutation (SNP) | VAF 36/85 reads (42%) | called by muse, mutect2, varscan2
- CUBN | c.9429G>A p.W3143* | Nonsense Mutation (SNP) | VAF 165/390 reads (42%) | called by muse, varscan2
- EXOSC10 | c.1376dup p.N460Qfs*30 | Frame Shift Ins (INS) | VAF 20/119 reads (17%) | called by mutect2, pindel, varscan2
- IGHG2 | c.404C>A p.T135N | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- LAMA3 | c.4194_4207del p.F1399Sfs*10 | Frame Shift Del (DEL) | VAF 51/152 reads (34%) | called by pindel, varscan2
- ME2 | c.1066_1072del p.A356* | Frame Shift Del (DEL) | VAF 50/106 reads (47%) | called by mutect2, pindel, varscan2
- PMFBP1 | c.7_12+3del p.X3_splice | Splice Site (DEL) | VAF 30/208 reads (14%) | called by mutect2, pindel
- RALGDS | c.1997_2000dup p.W668Afs*11 | Frame Shift Ins (INS) | VAF 25/137 reads (18%) | called by mutect2, pindel, varscan2
- SRFBP1 | c.1135_1152del p.N379_K384del | In Frame Del (DEL) | VAF 8/57 reads (14%) | called by mutect2, pindel
- TMCO6 | c.1390C>T p.Q464* | Nonsense Mutation (SNP) | VAF 105/261 reads (40%) | called by muse, mutect2, varscan2
- WDR20 | c.202_225del p.N68_F75del | In Frame Del (DEL) | VAF 13/36 reads (36%) | called by mutect2, pindel
- ACO2 | c.18A>G p.L6= | Silent (SNP) | VAF 26/148 reads (18%) | catalogued as rs1287910260, COSV53439481, COSV53440342; called by muse, mutect2, varscan2
- C19orf54 | c.867C>T p.S289= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV54573131; called by muse, mutect2, varscan2
- CAPZB | c.669A>G p.K223= | Silent (SNP) | VAF 36/162 reads (22%) | catalogued as COSV51644310; called by muse, mutect2, varscan2
- CD27 | c.42C>A p.T14= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV56949511; called by muse, mutect2, varscan2
- CDC42EP4 | c.669C>T p.S223= | Silent (SNP) | VAF 83/196 reads (42%) | catalogued as COSV59961895; called by muse, mutect2, varscan2
- CEACAM6 | c.324G>A p.L108= | Silent (SNP) | VAF 182/607 reads (30%) | catalogued as COSV52266435; called by muse, mutect2, varscan2
- EFCAB7 | c.1392T>C p.F464= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as rs1434890426, COSV64313924; called by muse, mutect2
- FAM126A | c.1179A>G p.E393= | Silent (SNP) | VAF 133/350 reads (38%) | catalogued as rs368769186; called by muse, mutect2, varscan2
- GIPR | c.63G>A p.Q21= | Silent (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- GNA14 | c.24C>T p.S8= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs765954210, COSV59018590; called by muse, mutect2, varscan2
- HDAC4 | c.2301G>A p.S767= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as rs200969154, COSV61859276; called by muse, mutect2, varscan2
- HEATR6 | c.969A>G p.P323= | Silent (SNP) | VAF 51/155 reads (33%) | catalogued as COSV51743672; called by muse, mutect2, varscan2
- INSC | c.765A>G p.T255= | Silent (SNP) | VAF 120/293 reads (41%) | catalogued as rs1219955633, COSV65408783; called by muse, mutect2, varscan2
- KCNA4 | c.723G>A p.L241= | Silent (SNP) | VAF 66/177 reads (37%) | catalogued as rs1564935989, COSV60250684; called by muse, mutect2, varscan2
- KIF12 | c.1296A>G p.L432= (on ENST00000640217; = p.L294= on NM_138424.1) | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as COSV65116614; called by muse, mutect2, varscan2
- LRP10 | c.537C>T p.F179= | Silent (SNP) | VAF 77/283 reads (27%) | catalogued as rs775127248, COSV62077657; called by muse, mutect2, varscan2
- MASP2 | c.921T>C p.P307= | Silent (SNP) | VAF 27/167 reads (16%) | catalogued as COSV68896076; called by muse, mutect2, varscan2
- MOS | c.54G>A p.S18= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs554770660, COSV61335915; called by muse, mutect2, varscan2
- MYOZ2 | c.699T>C p.N233= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as rs535274526, COSV61084055; called by muse, varscan2
- MYRIP | c.426C>T p.Y142= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs753830618, COSV100218472, COSV56862009; called by muse, varscan2
- NUP155 | c.3990A>G p.L1330= (on ENST00000231498 / NM_153485.3; = p.L1271= on NM_004298.4) | Silent (SNP) | VAF 79/244 reads (32%) | catalogued as COSV51526789; called by muse, mutect2, varscan2
- OR51A2 | c.639T>C p.I213= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV66748114; called by muse, mutect2, varscan2
- OR51A4 | c.639T>C p.I213= | Silent (SNP) | VAF 24/118 reads (20%) | called by muse, mutect2
- PAN2 | c.1050T>C p.S350= | Silent (SNP) | VAF 173/393 reads (44%) | catalogued as COSV57752675; called by muse, mutect2, varscan2
- PGM2 | c.1347G>A p.E449= | Silent (SNP) | VAF 64/154 reads (42%) | catalogued as COSV67938308; called by muse, mutect2, varscan2
- PKP4 | c.2424C>T p.I808= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs1321289038, COSV61577820; called by muse, mutect2, varscan2
- PNPT1 | c.999A>G p.P333= | Silent (SNP) | VAF 31/98 reads (32%) | catalogued as rs780916931, COSV53175682; called by muse, varscan2
- POFUT1 | c.381T>C p.F127= | Silent (SNP) | VAF 93/299 reads (31%) | catalogued as COSV65259988; called by muse, mutect2, varscan2
- SELP | c.1293T>C p.D431= | Silent (SNP) | VAF 48/83 reads (58%) | catalogued as COSV55248117; called by muse, mutect2, varscan2
- SLC6A16 | c.1533C>T p.S511= | Silent (SNP) | VAF 91/287 reads (32%) | catalogued as rs1434905399, COSV60026951; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2064C>T p.G688= (on ENST00000540229 / NM_001371097.1; = p.G627= on NM_001009562.4) | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV101042553, COSV67440321; called by muse, mutect2, varscan2
- SYCE1 | c.823C>A p.R275= (on ENST00000343131 / NM_001143764.3; = p.R239= on NM_130784.3) | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100385747, COSV58215856; called by muse, mutect2, varscan2
- TNFRSF4 | c.390A>G p.P130= | Silent (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- TPRA1 | c.759C>T p.I253= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs1272159502, COSV56160426; called by muse, mutect2, varscan2
- TRAF5 | c.360T>A p.V120= | Silent (SNP) | VAF 23/193 reads (12%) | catalogued as COSV54821086; called by muse, mutect2, varscan2
- TYK2 | c.1101C>T p.D367= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV53384726; called by muse, mutect2, varscan2
- VAC14 | c.30C>A p.L10= | Silent (SNP) | VAF 14/133 reads (11%) | catalogued as COSV55751060; called by muse, mutect2, varscan2
- VIPR1 | c.1296G>T p.T432= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV57296487; called by muse, mutect2
- ZBTB22 | c.312C>T p.A104= | Silent (SNP) | VAF 62/307 reads (20%) | catalogued as COSV56466583; called by muse, mutect2, varscan2
- CPLANE1 | c.*4381G>A | 3'UTR (SNP) | VAF 48/128 reads (38%) | catalogued as rs770320173, COSV57052191; called by muse, mutect2, varscan2
- EIF3A | c.1327-348G>C | Intron (SNP) | VAF 17/117 reads (15%) | catalogued as COSV100974491; called by muse, mutect2, varscan2
- LENG8 | c.*1900C>T | 3'UTR (SNP) | VAF 11/22 reads (50%) | catalogued as rs1455970245, COSV100002672; called by muse, mutect2
- NRM | c.*2G>A | 3'UTR (SNP) | VAF 28/139 reads (20%) | catalogued as COSV99223549; called by muse, mutect2, varscan2
- S1PR3 | chr9:88991066 del CGCTGTCAGGGCGACAGGCGCCCG | 5'Flank (DEL) | VAF 7/61 reads (11%) | called by mutect2, pindel
- TTN | c.10360+1724A>C | Intron (SNP) | VAF 51/157 reads (32%) | catalogued as COSV59886731; called by muse, mutect2, varscan2
